Somatic mutation profile of tumor specimen TCGA-CM-4744-01A (aliquot TCGA-CM-4744-01A-01D-1408-10) from TCGA case TCGA-CM-4744, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 69.8 years (25,506 days).
Specimen TCGA-CM-4744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdabb27a-e937-4b5d-a040-d4019b75b572.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4744-10A (Blood Derived Normal), aliquot TCGA-CM-4744-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ad4e10b-1c04-487c-97ca-d89cd5f4f1c7

The open-access MAF lists 160 somatic variants for this specimen: 119 protein-altering or splice-affecting, 41 silent.
By variant classification: Missense Mutation 100, Silent 41, Nonsense Mutation 7, Frame Shift Ins 6, Frame Shift Del 4, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.5791C>T p.R1931* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as rs1028186690, COSV51647667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 163/262 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AATK | c.134T>G p.V45G | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV58692025; called by muse, mutect2, varscan2
- AGTR1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763952495, COSV62557123; called by muse, mutect2, varscan2
- AKNAD1 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs752966432, COSV62203284; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 40/60 reads (67%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- AP2A1 | c.2452G>A p.G818S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.336); catalogued as rs1568590428, COSV100571236; called by muse, mutect2
- APC | c.4429C>T p.Q1477* | Nonsense Mutation (SNP) | VAF 50/88 reads (57%) | catalogued as CM106375, COSV57338033; called by muse, mutect2, varscan2
- AQP4 | c.801C>A p.S267R | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101270553; called by muse, mutect2, varscan2
- ARNTL2 | c.848dup p.C284Lfs*7 | Frame Shift Ins (INS) | VAF 32/184 reads (17%) | catalogued as rs1373896121; called by mutect2, pindel, varscan2
- ASIC2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1251980620, COSV56770077; called by muse, mutect2, varscan2
- ATP6V1B2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV52355184; called by muse, mutect2, varscan2
- BSN | c.3840T>G p.F1280L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56527047; called by muse, mutect2, varscan2
- C2CD3 | c.5209G>A p.G1737S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58100727; called by muse, mutect2
- C3orf20 | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV53789263; called by muse, mutect2, varscan2
- CCDC178 | c.2041G>T p.E681* (on ENST00000383096 / NM_001105528.3; = p.E643* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 95/190 reads (50%) | catalogued as COSV100284380, COSV55796493; called by muse, mutect2, varscan2
- CD276 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780694082, COSV59205662; called by muse, mutect2, varscan2
- CDC42BPG | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV61349160; called by muse, mutect2, varscan2
- CDRT1 | c.2126G>T p.R709I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1188106078, COSV63054353; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.234); catalogued as rs878855068, COSV51591716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN4 | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV101073969, COSV66468779; called by muse, mutect2
- CSMD2 | c.3253C>T p.R1085C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175679386, COSV53960205; called by muse, mutect2, varscan2
- DENND2C | c.2234G>T p.G745V (on ENST00000393274 / NM_001256404.2; = p.G688V on NM_198459.4) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67923985; called by muse, mutect2, varscan2
- DLG4 | c.1733G>A p.R578Q (on ENST00000399506 / NM_001321075.3; = p.R621Q on NM_001365.4) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.638); catalogued as rs914296410, COSV57242037; called by muse, mutect2
- DNAH2 | c.7963C>T p.R2655W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201837780, COSV66723125; called by muse, mutect2, varscan2
- DROSHA | c.2283G>T p.Q761H | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV60782521; called by muse, mutect2, varscan2
- DUSP8 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.647); catalogued as rs1236082470, COSV100524477; called by muse, mutect2
- EIF3A | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64963353, COSV64963460; called by muse, mutect2, varscan2
- ENG | c.176A>T p.N59I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100785333; called by muse, mutect2, varscan2
- EXOC6B | c.327A>T p.E109D | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.931); catalogued as COSV55572171; called by muse, mutect2, varscan2
- FAM155A | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.187); catalogued as COSV65563899, COSV65586590; called by muse, mutect2, varscan2
- FCGBP | c.6595G>A p.V2199M | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1331642615, COSV55426569; called by muse, mutect2, varscan2
- FIGN | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166718690, COSV60771668; called by muse, mutect2, varscan2
- FNDC1 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1417434518, COSV51947634; called by muse, mutect2, varscan2
- GABRG1 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54961475; called by muse, mutect2, varscan2
- GABRQ | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs782155034, COSV64781574; called by muse, mutect2, varscan2
- GFRA1 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.96); catalogued as rs367892328; called by muse, mutect2, varscan2
- GFRA2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs901943236; called by muse, mutect2
- GPR15 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs756664994, COSV52521423; called by muse, mutect2, varscan2
- HIVEP2 | c.3203C>T p.T1068M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs187442388; called by muse, mutect2, varscan2
- HTR1A | c.470T>A p.I157N | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109224; called by muse, mutect2
- IFI44L | c.976A>G p.N326D | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV60729370; called by muse, mutect2, varscan2
- IGSF9 | c.3436C>T p.R1146W (on ENST00000368094 / NM_001135050.2; = p.R1130W on NM_020789.4) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs763910745, COSV57422141, COSV57422710; called by muse, mutect2, varscan2
- ILF2 | c.1155C>A p.S385R | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.207); catalogued as COSV62628212; called by muse, mutect2, varscan2
- ISLR2 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62303359; called by muse, mutect2, varscan2
- ITGAX | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV51651332; called by muse, mutect2, varscan2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 10/61 reads (16%) | catalogued as rs760028800; called by mutect2, varscan2
- KATNAL2 | c.764A>G p.D255G (on ENST00000356157 / NM_001353899.1; = p.D183G on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV55308291; called by muse, mutect2, varscan2
- KCNB2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73049819; called by muse, mutect2, varscan2
- KCNH8 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1209130097, COSV60469245, COSV60476143; called by muse, mutect2, varscan2
- KRT8 | c.230T>G p.V77G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53179144; called by muse, mutect2, varscan2
- LIG4 | c.2328A>T p.E776D | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63598053; called by muse, mutect2, varscan2
- LRRK2 | c.5878C>A p.Q1960K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.237); catalogued as COSV54169936; called by muse, mutect2, varscan2
- MAP3K21 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.21); catalogued as rs779186370, COSV64044049; called by muse, mutect2, varscan2
- MEI1 | c.1976T>G p.L659R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55907653; called by muse, mutect2, varscan2
- MGP | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); catalogued as rs753350275, COSV57454123; called by muse, mutect2, varscan2
- MKI67 | c.8723C>A p.P2908H | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.288); catalogued as COSV100896493; called by muse, mutect2
- MTA1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs782330213, COSV58760322; called by muse, mutect2, varscan2
- MYO6 | c.3527G>T p.R1176L (on ENST00000369981; = p.R1166L on NM_004999.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs769185775, COSV64121311; called by muse, mutect2, varscan2
- NAP1L2 | c.1070C>G p.T357R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65173062; called by muse, mutect2, varscan2
- NRXN1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.759); catalogued as rs1415234353, COSV68046141; called by muse, mutect2
- NUB1 | c.1205C>A p.S402* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV63427654; called by muse, mutect2, varscan2
- NYAP2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.855); catalogued as rs1313066722, COSV55998861; called by muse, mutect2, varscan2
- OR10X1 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1490780659, COSV63767716, COSV63767989; called by muse, mutect2, varscan2
- OR2AK2 | c.935G>T p.R312I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV63560666; called by muse, mutect2, varscan2
- OR5D13 | c.484A>C p.T162P | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62334321, COSV62335302; called by muse, mutect2, varscan2
- OR5D13 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV62335311; called by muse, mutect2, varscan2
- OSMR | c.691del p.L231Ffs*68 | Frame Shift Del (DEL) | VAF 37/204 reads (18%) | catalogued as COSV57091621, COSV99953019, COSV99953075; called by mutect2, pindel, varscan2
- PABPC5 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs772523316, COSV57040186, COSV57043239; called by muse, mutect2, varscan2
- PAPPA2 | c.3705G>A p.W1235* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV62799338, COSV62811095; called by muse, mutect2, varscan2
- PCDH15 | c.5331G>T p.K1777N | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious, low confidence (0.02); catalogued as rs749874091, COSV64681994, COSV64735853; called by muse, mutect2, varscan2
- PCDHA5 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs370639569; called by muse, mutect2
- PGLYRP3 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV51952758; called by muse, mutect2, varscan2
- PIK3CD | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.196); catalogued as COSV63131754, COSV63131878; called by muse, mutect2, varscan2
- PKD2L2 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51801539; called by muse, mutect2
- PKP1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs139909774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXDC2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372336202; called by muse, mutect2, varscan2
- POLQ | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1004298328, COSV99952684; called by muse, mutect2
- PPFIA1 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs141485507; called by muse, mutect2, varscan2
- RANBP2 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV51708477; called by muse, varscan2
- RASSF10 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1349465208, COSV61754680; called by muse, mutect2, varscan2
- RNF10 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770748090, COSV100378894; called by muse, mutect2, varscan2
- RNF148 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1323821083, COSV100411704; called by muse, mutect2
- RNF180 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99684884; called by muse, mutect2, varscan2
- RTN1 | c.1391G>A p.S464N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV50736980; called by muse, mutect2, varscan2
- SCN4A | c.3221A>G p.Y1074C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV71128984; called by muse, mutect2, varscan2
- SCUBE3 | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368342758, COSV51457156; called by muse, mutect2, varscan2
- SETX | c.7259T>G p.F2420C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56394322; called by muse, mutect2, varscan2
- SHC4 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs758064025, COSV60116539; called by muse, mutect2, varscan2
- SLC12A6 | c.2003G>A p.R668Q (on ENST00000354181 / NM_001365088.1; = p.R617Q on NM_005135.2) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs779359867, COSV51631429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A11 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs990142958, COSV66263879; called by muse, mutect2, varscan2
- SLC8A2 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV52642893, COSV52643029; called by muse, mutect2, varscan2
- SOX11 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs775298170, COSV100431339; called by muse, mutect2
- SPANXD | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as COSV65153249; called by muse, mutect2
- SPOUT1 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs748580465, COSV63510292; called by muse, mutect2, varscan2
- SPTAN1 | c.6119A>G p.K2040R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV100823893; called by muse, mutect2, varscan2
- STAB1 | c.3562C>T p.R1188W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs367750960, COSV58742817; called by muse, mutect2, varscan2
- TADA2B | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs1374921983, COSV53828252; called by muse, mutect2, varscan2
- TCF4 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61906098; called by muse, mutect2, varscan2
- THSD7B | c.2807A>G p.D936G | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV99756395; called by muse, mutect2, varscan2
- TRPS1 | c.3335G>A p.R1112Q (on ENST00000220888 / NM_001330599.2; = p.R1125Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773593651, COSV55261368; called by muse, mutect2, varscan2
- UFL1 | c.1664A>G p.E555G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV65150688; called by muse, mutect2, varscan2
- USP18 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV53174441; called by muse, mutect2, varscan2
- VCL | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs534101808, COSV53014542; called by muse, mutect2, varscan2
- VPS13D | c.10930C>T p.R3644C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50681268; called by muse, mutect2, varscan2
- XKR4 | c.666C>A p.S222R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.398); catalogued as COSV59338525; called by muse, mutect2, varscan2
- ZBTB7A | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1393341344, COSV59326517; called by muse, mutect2, varscan2
- ZNF277 | c.1300T>G p.S434A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as COSV100702517; called by muse, mutect2, varscan2
- ZNF549 | c.1133G>A p.R378Q (on ENST00000376233 / NM_001199295.2; = p.R365Q on NM_153263.2) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.3); catalogued as rs199998659, COSV53723486; called by muse, mutect2, varscan2
- CLUH | c.2919del p.K974Rfs*21 (on ENST00000435359; = p.K1013Rfs*21 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- EXOC2 | c.1961_1963del p.E654del | In Frame Del (DEL) | VAF 35/146 reads (24%) | called by pindel, varscan2
- FBXW7 | c.1252_1259dup p.H420Qfs*13 (on ENST00000281708 / NM_001349798.2; = p.H340Qfs*13 on NM_018315.5) | Frame Shift Ins (INS) | VAF 30/77 reads (39%) | called by mutect2, pindel, varscan2
- GPRASP2 | c.1976dup p.L659Ffs*18 | Frame Shift Ins (INS) | VAF 41/148 reads (28%) | called by mutect2, pindel, varscan2
- IGKV1D-43 | c.153T>G p.I51M | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- IGKV2D-30 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX9 | c.872_875dup p.E293Qfs*4 | Frame Shift Ins (INS) | VAF 36/72 reads (50%) | called by mutect2, pindel, varscan2
- TEX2 | c.2706dup p.S903Vfs*17 (on ENST00000583097 / NM_001288733.2; = p.S910Vfs*17 on NM_018469.5) | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.1262del p.P421Lfs*65 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- TTC13 | c.1880_1881del p.R627Nfs*8 | Frame Shift Del (DEL) | VAF 28/165 reads (17%) | called by mutect2, pindel, varscan2
- ANXA7 | c.363A>G p.P121= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100873486; called by muse, mutect2
- ARHGAP4 | c.2118C>T p.Y706= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as rs934349924, COSV61686543; called by muse, mutect2, varscan2
- ATAD1 | c.303G>A p.T101= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs767153294, COSV100057881, COSV57758712; called by muse, mutect2, varscan2
- BNC2 | c.2055C>A p.G685= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV66156830; called by muse, mutect2, varscan2
- BRSK1 | c.1401C>T p.G467= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV58669996; called by muse, mutect2, varscan2
- CCDC88A | c.2958C>G p.S986= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as COSV55069714; called by muse, mutect2, varscan2
- CPA5 | c.1089C>T p.I363= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs899474752, COSV62570746; called by muse, mutect2, varscan2
- DAGLA | c.3045G>A p.A1015= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs749910641, COSV57193985; called by muse, mutect2, varscan2
- DCAF4L1 | c.735C>T p.S245= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs779679144, COSV60788568; called by muse, mutect2, varscan2
- DNAH10 | c.7059A>C p.I2353= (on ENST00000409039; = p.I2292= on NM_207437.3) | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV101292494; called by muse, mutect2, varscan2
- DPH7 | c.825G>A p.P275= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs374074310; called by muse, mutect2, varscan2
- FAM151A | c.843G>A p.S281= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs199978172, COSV56366250; called by muse, mutect2, varscan2
- FBN3 | c.7671C>T p.F2557= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1342789515, COSV54455441; called by muse, mutect2, varscan2
- FBXO46 | c.378C>T p.S126= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs766121787, COSV58348871; called by muse, mutect2, varscan2
- FEZF2 | c.1236C>T p.N412= | Silent (SNP) | VAF 9/141 reads (6%) | catalogued as COSV99334915; called by muse, mutect2
- GOLGB1 | c.6615A>T p.I2205= | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as COSV61465479, COSV61470846; called by muse, mutect2, varscan2
- IQCN | c.603C>T p.V201= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV66577647; called by muse, mutect2
- LRCH4 | c.1086C>T p.P362= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs761154684, COSV59644546; called by muse, mutect2, varscan2
- LSAMP | c.912C>A p.V304= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV61310208; called by muse, mutect2, varscan2
- MOV10L1 | c.1368G>A p.A456= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs199858235, COSV53178862; called by muse, mutect2, varscan2
- MUC5B | c.5778G>A p.P1926= | Silent (SNP) | VAF 45/200 reads (23%) | catalogued as rs753835109; called by muse, mutect2, varscan2
- NELFA | c.1491G>A p.T497= (on ENST00000542778; = p.T486= on NM_005663.5) | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as rs377133609, COSV56386709; called by muse, mutect2, varscan2
- NRROS | c.804G>A p.L268= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV60747747; called by muse, mutect2, varscan2
- PCDHGC5 | c.2166C>T p.D722= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV52767557; called by muse, mutect2, varscan2
- PKD2 | c.2634G>A p.R878= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV52941242; called by muse, mutect2, varscan2
- PRDM16 | c.219C>T p.Y73= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV54608022; called by muse, mutect2, varscan2
- PRMT1 | c.315T>C p.F105= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV67160362; called by muse, mutect2, varscan2
- RASGRF1 | c.339C>T p.D113= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs201439198; called by muse, mutect2, varscan2
- SCN1A | c.2004G>T p.L668= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV57686840; called by muse, mutect2
- SHANK2 | c.2751C>T p.Y917= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs1373082612, COSV53589175; called by muse, mutect2
- SLC2A11 | c.528C>T p.V176= (on ENST00000345044 / NM_001024938.4; = p.V183= on NM_030807.5) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs772132279, COSV55393810; called by muse, mutect2, varscan2
- SRC | c.1278A>G p.K426= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100658176; called by muse, mutect2, varscan2
- STAT5A | c.819C>T p.D273= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs942718644, COSV61808395; called by muse, mutect2, varscan2
- STK33 | c.1464C>A p.T488= | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as COSV100173646, COSV59409269; called by muse, mutect2, varscan2
- THEG | c.111C>T p.Y37= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs758840282, COSV61073975; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2709C>T p.N903= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs769313015, COSV64102562; called by muse, mutect2, varscan2
- TUBA3C | c.411C>T p.I137= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV101262820; called by muse, mutect2, varscan2
- TUBGCP2 | c.330C>T p.A110= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs987869197, COSV99428207; called by muse, mutect2
- TULP1 | c.339C>T p.D113= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs1174337620, COSV57693836; called by muse, mutect2, varscan2
- TWIST1 | c.384C>T p.F128= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs748239205, COSV54251519; called by muse, mutect2, varscan2
- ZNF71 | c.1407C>T p.G469= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs754639538, COSV60150041; called by muse, mutect2, varscan2
